Somatic mutation profile of tumor specimen TCGA-FD-A43U-01A (aliquot TCGA-FD-A43U-01A-11D-A23U-08) from TCGA case TCGA-FD-A43U, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 70.7 years (25,841 days).
Specimen TCGA-FD-A43U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 101fabea-58b5-4f3f-ba5f-616e98f06902.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A43U-10A (Blood Derived Normal), aliquot TCGA-FD-A43U-10A-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/53873fc4-c0c3-43c5-ad2b-cd453ebb507a

The open-access MAF lists 78 somatic variants for this specimen: 54 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Splice Region 1, 3'UTR 1, 3'Flank 1, Nonsense Mutation 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.1289G>C p.R430P | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV59200440; called by muse, mutect2
- ANK1 | c.2768G>A p.G923D | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55886435; called by muse, mutect2, varscan2
- ANKRD24 | c.535C>T p.R179W | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1301064400, COSV53670697, COSV53672678; called by muse, mutect2
- ANKRD7 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV54555312; called by muse, mutect2
- APEH | c.1853C>T p.S618F | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV56535047; called by muse, mutect2, varscan2
- APOL2 | c.776G>C p.R259T | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV50772375; called by muse, mutect2
- ARFGEF3 | c.872C>T p.S291L | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs755452517, COSV52454593; called by muse, mutect2
- ATP6V1C2 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs763804757, COSV55360671, COSV55362051; called by muse, mutect2
- C17orf75 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.173); catalogued as COSV56753277; called by muse, mutect2, varscan2
- CAND1 | c.286C>G p.L96V | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as COSV73338619; called by muse, mutect2, varscan2
- CAND1 | c.580A>G p.R194G | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV73338620; called by muse, mutect2, varscan2
- CDH17 | c.136C>A p.Q46K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.164); catalogued as COSV99217314; called by muse, mutect2
- CDH23 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 37/262 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV54941748; called by muse, mutect2
- CREB5 | c.1469G>A p.G490E (on ENST00000357727 / NM_182898.4; = p.G483E on NM_004904.3) | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV63224053; called by muse, mutect2, varscan2
- CRMP1 | c.290T>C p.L97P | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61481346; called by muse, mutect2, varscan2
- CRMP1 | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs766297812, COSV61481355, COSV61482465; called by muse, mutect2, varscan2
- CYCS | c.59C>A p.T20N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV59872743; called by muse, mutect2, varscan2
- DCBLD1 | c.1118C>T p.S373F | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51643175; called by muse, mutect2
- DLG1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV58386284; called by muse, mutect2, varscan2
- ENAM | c.1675C>T p.H559Y | Missense Mutation (SNP) | VAF 19/190 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as COSV68536462; called by muse, mutect2
- EPS15 | c.1303A>T p.S435C | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV65543521; called by muse, mutect2, varscan2
- FAM155A | c.707C>A p.S236* | Nonsense Mutation (SNP) | VAF 39/224 reads (17%) | catalogued as COSV101027584; called by muse, mutect2, varscan2
- FLNB | c.6875T>G p.V2292G | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55885238; called by muse, mutect2, varscan2
- HMGCS1 | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV57290725; called by muse, mutect2, varscan2
- HYDIN | c.3721G>T p.A1241S | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.059); catalogued as COSV101142004, COSV66832846; called by muse, mutect2
- IL20RA | c.908C>G p.P303R | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100359909; called by muse, mutect2
- ISLR2 | c.1884C>G p.I628M | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62302712; called by muse, mutect2, varscan2
- ITPRID1 | c.2287C>A p.Q763K | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60077701; called by muse, mutect2
- IYD | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs1334148969, COSV57602099; called by muse, mutect2
- KANK4 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV62987708; called by muse, mutect2
- KCNB2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1400578397, COSV73048697; called by muse, mutect2
- KDM3A | c.1738A>G p.K580E | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV57223128; called by muse, mutect2, varscan2
- LAMA1 | c.3279C>A p.D1093E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.094); catalogued as COSV101055998; called by muse, mutect2
- MYCBP2 | c.3685C>T p.L1229F (on ENST00000357337; = p.L1267F on NM_015057.5) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.7); catalogued as COSV62027667; called by muse, mutect2
- MYH9 | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV53389199; called by muse, mutect2
- MYLK | c.1226G>A p.R409K | Missense Mutation (SNP) | VAF 27/194 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs776506361, COSV60614553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NCOA6 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV62865434, COSV62868941; called by muse, mutect2, varscan2
- NFASC | c.1474C>T p.R492C (on ENST00000339876 / NM_001378329.1; = p.R503C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/214 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs531423904, COSV100362363, COSV58358373; called by muse, mutect2
- NOL6 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53041034, COSV53043361; called by muse, mutect2
- NUP214 | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as rs754496000, COSV55990487; called by muse, mutect2
- PRKRA | c.412C>A p.H138N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as COSV100359538; called by muse, mutect2
- PTPRS | c.4294C>T p.R1432C | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53626433; called by muse, mutect2, varscan2
- QPCTL | c.1037T>A p.F346Y | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50004194; called by muse, mutect2
- RP1L1 | c.750C>T p.N250= | Splice Region (SNP) | VAF 21/140 reads (15%) | catalogued as rs552702623, COSV61446246; called by muse, mutect2, varscan2
- SPHKAP | c.1349T>A p.I450N | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60885263; called by muse, mutect2, varscan2
- STAU2 | c.1185T>A p.S395R (on ENST00000524300 / NM_001164380.2; = p.S363R on NM_014393.2) | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV63309416; called by muse, mutect2, varscan2
- TMEM37 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 16/218 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs772027165, COSV50027516; called by muse, mutect2
- TSHZ3 | c.2680C>T p.R894C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53675723; called by muse, mutect2
- XRN2 | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.225); catalogued as COSV65870421; called by muse, mutect2, varscan2
- ZMIZ2 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 53/751 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747725017, COSV54807381; called by muse, mutect2
- MRC1 | c.3248C>T p.S1083F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.049); called by muse, mutect2
- POM121 | c.2246C>T p.S749L (on ENST00000434423; = p.S484L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/276 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2
- ZFP36L1 | c.230_231dup p.A78Pfs*3 | Frame Shift Ins (INS) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- ZNF57 | c.752del p.P251Hfs*21 | Frame Shift Del (DEL) | VAF 18/126 reads (14%) | called by mutect2, pindel, varscan2
- ANKRD23 | c.917G>A p.*306= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100450400; called by muse, varscan2
- APEH | c.1854C>T p.S618= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV56535056; called by muse, mutect2, varscan2
- APOBEC3A | c.99G>A p.L33= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as COSV50779556; called by muse, mutect2
- CAPN7 | c.450G>A p.L150= | Silent (SNP) | VAF 11/70 reads (16%) | catalogued as COSV53779380; called by muse, mutect2, varscan2
- CREB3L1 | c.849C>A p.L283= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as COSV55832056; called by muse, mutect2, varscan2
- DLG1 | c.12G>A p.R4= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs764525682, COSV58386267; called by muse, mutect2, varscan2
- DNAH11 | c.13245G>A p.K4415= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV100178828; called by muse, mutect2
- DNAH17 | c.11880G>A p.E3960= | Silent (SNP) | VAF 21/134 reads (16%) | catalogued as COSV67757775; called by muse, mutect2, varscan2
- FBXO41 | c.931C>T p.L311= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs373307826, COSV54586592; called by muse, mutect2, varscan2
- FBXO41 | c.930C>T p.F310= | Silent (SNP) | VAF 20/125 reads (16%) | catalogued as COSV54586614; called by muse, mutect2, varscan2
- FRYL | c.2967G>T p.L989= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV51952466; called by muse, varscan2
- HLF | c.375C>T p.D125= | Silent (SNP) | VAF 81/350 reads (23%) | catalogued as COSV56830717; called by muse, mutect2, varscan2
- HPS3 | c.27G>A p.P9= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs778074312, COSV56052373; called by muse, mutect2, varscan2
- KANSL3 | c.1656G>A p.Q552= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV62619192; called by muse, mutect2, varscan2
- LEFTY2 | c.861C>A p.G287= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV64747275; called by muse, mutect2
- MC3R | c.643C>A p.R215= | Silent (SNP) | VAF 12/166 reads (7%) | catalogued as rs773966315, COSV54763095; called by muse, mutect2
- MET | c.2208C>T p.F736= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV100577170, COSV59262829; called by muse, mutect2
- PCDHGB5 | c.684C>T p.L228= | Silent (SNP) | VAF 43/195 reads (22%) | catalogued as rs1231007055; called by muse, mutect2, varscan2
- PMM2 | c.33C>T p.F11= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV51632665; called by muse, mutect2
- RIPOR3 | c.1561C>T p.L521= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV50393658; called by muse, mutect2, varscan2
- S1PR5 | c.1113C>T p.D371= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs1414666740, COSV61014195; called by muse, mutect2
- TTC21A | c.2724G>T p.A908= | Silent (SNP) | VAF 20/85 reads (24%) | catalogued as COSV57186693; called by muse, mutect2, varscan2
- ACBD7 | c.*1A>G | 3'UTR (SNP) | VAF 11/76 reads (14%) | catalogued as COSV100650407; called by muse, varscan2
- RUFY2 | chr10:68341222 G>A | 3'Flank (SNP) | VAF 6/82 reads (7%) | catalogued as COSV56260148; called by muse, mutect2
